Somatic mutation profile of tumor specimen TCGA-AJ-A2QM-01A (aliquot TCGA-AJ-A2QM-01A-11D-A18P-09) from TCGA case TCGA-AJ-A2QM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.8 years (24,776 days).
Specimen TCGA-AJ-A2QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06828fcc-2196-421d-a604-9d5d04172013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A2QM-10A (Blood Derived Normal), aliquot TCGA-AJ-A2QM-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6eeb8c8-fc18-4031-8ecb-0680bd94cb00

The open-access MAF lists 190 somatic variants for this specimen: 148 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 41, Nonsense Mutation 11, Splice Region 2, Frame Shift Del 2, In Frame Del 1, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 164/169 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS16 | c.3409C>G p.Q1137E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99943351; called by muse, mutect2, varscan2
- ADCY9 | c.3840C>A p.N1280K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV53572950, COSV99571004; called by muse, mutect2
- ADGRB1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs267601806, COSV60103536; called by muse, mutect2, varscan2
- AGPAT1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100421740; called by muse, mutect2, varscan2
- AK9 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100394460; called by muse, mutect2, varscan2
- AKAP8 | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99512222; called by muse, mutect2
- ALKBH4 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV52961228, COSV99479595; called by muse, mutect2, varscan2
- AMBN | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100534533; called by muse, mutect2, varscan2
- AMBRA1 | c.1621G>C p.E541Q (on ENST00000458649 / NM_001367468.1; = p.E451Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV100095562, COSV54052409; called by muse, mutect2, varscan2
- AP2A2 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100173404; called by muse, mutect2, varscan2
- ARAF | c.1551G>T p.Q517H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99283478; called by mutect2, varscan2
- BIRC6 | c.4616C>G p.S1539* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV101429135; called by muse, mutect2, varscan2
- BTBD10 | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99533973; called by muse, mutect2, varscan2
- BTK | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.887); catalogued as rs1555978130, COSV100437985, COSV58124791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf46 | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs746831628, COSV100215495; called by muse, mutect2, varscan2
- C1orf87 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV64597574; called by muse, mutect2, varscan2
- C3orf20 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.43); catalogued as rs763094982, COSV99514662; called by muse, mutect2, varscan2
- CA8 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV100527353; called by muse, mutect2, varscan2
- CASP8 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99966165; called by muse, mutect2, varscan2
- CCDC173 | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV101506385; called by muse, mutect2
- CCN1 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101486145; called by muse, mutect2
- CCNE1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99388679; called by muse, mutect2, varscan2
- CD226 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs745995433, COSV99711590; called by muse, mutect2, varscan2
- CDC5L | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV101015244; called by muse, mutect2, varscan2
- CDK10 | c.806T>G p.L269R (on ENST00000353379 / NM_052988.5; = p.L198R on NM_052987.4) | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99232555; called by muse, mutect2
- CIB4 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as COSV99995147; called by muse, mutect2, varscan2
- COL4A3 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV67412971; called by muse, mutect2, varscan2
- COL9A1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV100611767; called by muse, mutect2, varscan2
- CREB3L2 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as COSV100382375; called by muse, mutect2, varscan2
- DBP | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV55335155, COSV99709684; called by muse, mutect2, varscan2
- DCC | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100502243; called by muse, mutect2, varscan2
- DENND5B | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV100172331; called by muse, mutect2, varscan2
- DICER1 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.942); catalogued as COSV100602630, COSV58626683, COSV58630003; called by muse, mutect2, varscan2
- DMKN | c.1197C>G p.F399L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100304011; called by muse, mutect2, varscan2
- DYRK1A | c.1991C>G p.S664C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100118369; called by muse, mutect2, varscan2
- DZIP3 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100848120; called by muse, mutect2, varscan2
- ELL | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99443817; called by muse, mutect2
- ELOA2 | c.1947G>C p.K649N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99798403; called by muse, mutect2, varscan2
- ENC1 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.242); catalogued as COSV100188282; called by muse, mutect2, varscan2
- FAM98C | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV53040030, COSV99385180; called by muse, mutect2, varscan2
- FARP1 | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100132289; called by muse, mutect2, varscan2
- FARS2 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99213359; called by muse, mutect2, varscan2
- FKBP9 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.944); catalogued as COSV99640594; called by muse, mutect2
- FOXN1 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99881593; called by muse, mutect2, varscan2
- FREM1 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV101085638, COSV66518614; called by mutect2, varscan2
- GIPC1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs766409659, COSV99466690; called by muse, mutect2, varscan2
- GPC2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52783645, COSV52786686, COSV99445165; called by muse, mutect2, varscan2
- GPN3 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57402219, COSV99960021; called by mutect2, varscan2
- GPR141 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100550500; called by muse, mutect2, varscan2
- GPR149 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101078816; called by muse, mutect2, varscan2
- GRIK3 | c.2746C>A p.P916T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100902407; called by muse, mutect2, varscan2
- GRIK3 | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100902408; called by muse, mutect2, varscan2
- H2BC8 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99773434; called by muse, mutect2, varscan2
- HECW2 | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99649296; called by muse, mutect2, varscan2
- HERC6 | c.892C>G p.H298D | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52029660, COSV99910431; called by muse, mutect2, varscan2
- HRH1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101229122; called by muse, mutect2
- ICE2 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937747827, COSV99831898; called by muse, mutect2, varscan2
- IHO1 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.234); catalogued as COSV56507398; called by muse, mutect2, varscan2
- IKZF1 | c.1377G>C p.M459I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100498835; called by muse, mutect2, varscan2
- INTS2 | c.3189C>A p.H1063Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99248976; called by muse, mutect2
- JARID2 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100522577; called by muse, mutect2, varscan2
- KANSL3 | c.1846G>A p.E616K (on ENST00000666923 / NM_001349262.2; = p.E590K on NM_001115016.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV100831262; called by muse, mutect2, varscan2
- KCNK6 | c.624C>G p.C208W | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649514; called by muse, mutect2, varscan2
- LAMA3 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557763; called by muse, mutect2, varscan2
- LGI2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV101180959; called by muse, mutect2, varscan2
- MAP6 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1248367818, COSV100496964; called by muse, mutect2, varscan2
- MDC1 | c.3064G>A p.A1022T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as COSV100903127; called by muse, mutect2, varscan2
- MED12 | c.3640C>A p.R1214S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100380286; called by muse, mutect2, varscan2
- MEFV | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as rs368981831; called by muse, mutect2, varscan2
- MIA3 | c.4024G>T p.V1342L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100485260; called by muse, mutect2
- MICB | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV52855962; called by muse, mutect2, varscan2
- MON2 | c.3185C>G p.S1062* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99743862; called by muse, mutect2
- MROH2B | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101270960, COSV68185545; called by muse, mutect2, varscan2
- MRPL9 | c.438G>C p.L146= | Splice Region (SNP) | VAF 32/96 reads (33%) | catalogued as rs1438161679, COSV100162743; called by muse, mutect2, varscan2
- MRPS10 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754001754, COSV99273685; called by muse, mutect2, varscan2
- MS4A3 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53937981; called by muse, mutect2, varscan2
- MS4A6A | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV100125139; called by muse, mutect2, varscan2
- MSLN | c.1892G>C p.*631Sext*35 (on ENST00000382862 / NM_013404.4; = p.*623Sext*35 on NM_005823.6) | Nonstop Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99558877; called by muse, mutect2, varscan2
- MUC16 | c.13640C>T p.S4547L | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.569); catalogued as COSV101202017, COSV67488515; called by muse, mutect2, varscan2
- MUSK | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV51897454, COSV99505267; called by muse, mutect2, varscan2
- MYH2 | c.5041G>T p.E1681* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as CM152305, COSV99821134; called by muse, mutect2, varscan2
- MZF1 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs371153551, COSV53041187; called by muse, mutect2, varscan2
- NCAPD3 | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV101599405, COSV73258990; called by muse, mutect2, varscan2
- NCKAP5 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58444543; called by muse, mutect2, varscan2
- NFX1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100582509; called by mutect2, varscan2
- NLRP5 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV101173935; called by muse, mutect2, varscan2
- NR2C2AP | c.57T>G p.N19K | Missense Mutation (SNP) | VAF 108/152 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100284655; called by muse, mutect2, varscan2
- NUP153 | c.3413C>G p.S1138* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100020930; called by muse, mutect2, varscan2
- OBSCN | c.23277G>A p.E7759= | Splice Region (SNP) | VAF 37/93 reads (40%) | catalogued as COSV100806181; called by muse, mutect2, varscan2
- OPRM1 | c.361A>G p.S121G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100002627; called by muse, mutect2
- OR6K6 | c.355A>G p.S119G (on ENST00000368144; = p.S95G on NM_001005184.1) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100933808; called by muse, mutect2, varscan2
- OR8H2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV57947566; called by muse, mutect2, varscan2
- PCNT | c.8588G>C p.R2863T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100856116; called by muse, mutect2
- PCNX1 | c.2645C>T p.T882M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as rs373030328; called by muse, mutect2, varscan2
- PDGFRB | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as COSV99941020; called by muse, mutect2, varscan2
- PHLDB2 | c.2215G>C p.E739Q (on ENST00000393925 / NM_001134439.2; = p.E696Q on NM_145753.2) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101208760; called by muse, mutect2, varscan2
- PKD1L1 | c.1784G>C p.R595P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56963991, COSV99221622; called by muse, mutect2, varscan2
- PMEL | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100657116; called by muse, mutect2, varscan2
- PPFIA2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100335505; called by muse, mutect2, varscan2
- PPP1CB | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99941999; called by muse, mutect2, varscan2
- PPP2R1A | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100436537; called by muse, mutect2, varscan2
- PPP2R1A | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV59043910; called by muse, mutect2, varscan2
- PSEN2 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV60917488; called by muse, mutect2, varscan2
- PSMA3 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99373558; called by muse, mutect2, varscan2
- PSMD14 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV101293960; called by muse, mutect2, varscan2
- RNF32 | c.944G>C p.R315T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV58734761; called by muse, mutect2, varscan2
- ROCK1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV101296645; called by muse, mutect2, varscan2
- RORC | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100562169; called by muse, mutect2, varscan2
- RORC | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100562172; called by muse, mutect2, varscan2
- RUFY3 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56915361; called by muse, mutect2, varscan2
- SAGE1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV61015459; called by muse, mutect2, varscan2
- SALL3 | c.3183C>G p.I1061M | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV73306804; called by muse, mutect2
- SAMD4B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100080350, COSV58750100, COSV58753067; called by muse, mutect2, varscan2
- SDF4 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV99767959; called by muse, mutect2
- SGK1 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as rs1170253783, COSV99399270; called by muse, mutect2, varscan2
- SH2D4A | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as COSV56122627; called by muse, mutect2
- SI | c.741G>C p.K247N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV100017436; called by muse, mutect2, varscan2
- SLIT3 | c.957C>G p.I319M | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100270440; called by muse, mutect2, varscan2
- SMARCA5 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV51645663; called by muse, mutect2, varscan2
- SPATA4 | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99709131; called by muse, mutect2, varscan2
- SREBF2 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.63); catalogued as COSV100761586, COSV63330574; called by muse, mutect2, varscan2
- SRP19 | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99295398; called by muse, mutect2, varscan2
- STPG1 | c.718C>T p.P240S (on ENST00000337248 / NM_001199013.2; = p.P193S on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV99134518; called by muse, mutect2, varscan2
- SUPT6H | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100112862, COSV58925784; called by muse, mutect2, varscan2
- SYTL4 | c.1805G>A p.W602* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99343426; called by muse, mutect2, varscan2
- TAP1 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV100841336; called by muse, mutect2, varscan2
- TBC1D23 | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792776; called by muse, mutect2, varscan2
- TBC1D4 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs771093387, COSV66488590, COSV66490927; called by muse, mutect2, varscan2
- TFPT | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99500113; called by muse, mutect2, varscan2
- TMEM203 | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV100411293; called by muse, mutect2, varscan2
- TMEM26 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs1017279780, COSV53262420; called by muse, mutect2
- TOP1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV100793984; called by muse, mutect2, varscan2
- TRPM2 | c.2194C>T p.H732Y | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55967750; called by muse, mutect2, varscan2
- TTC3 | c.4693G>C p.E1565Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100696130; called by muse, mutect2, varscan2
- UBQLN3 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV100294005, COSV61164323; called by muse, mutect2, varscan2
- UNC13A | c.3141C>G p.F1047L | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99408285, COSV99409787; called by muse, mutect2
- USP34 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs758766334, COSV101277271, COSV68406444; called by muse, mutect2, varscan2
- ZBTB7B | c.824del p.G275Vfs*40 (on ENST00000292176; = p.G309Vfs*40 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/39 reads (54%) | catalogued as COSV99421460; called by mutect2, pindel, varscan2
- ZC3H18 | c.1634C>A p.S545* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99964537; called by muse, mutect2, varscan2
- ZNF260 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV101591076; called by muse, mutect2, varscan2
- ZNF831 | c.3607G>T p.A1203S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100926310; called by muse, mutect2, varscan2
- ZNF883 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV71309000; called by muse, mutect2, varscan2
- ACBD4 | c.289_290dup p.Q97Hfs*4 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by pindel, varscan2
- COL15A1 | c.346_348del p.K116del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- MLLT6 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PGR | c.2157_2160del p.Q720* | Frame Shift Del (DEL) | VAF 25/40 reads (63%) | called by mutect2, pindel, varscan2
- AFF4 | c.1434G>A p.L478= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs913498638, COSV54797666; called by muse, mutect2, varscan2
- AHCY | c.1086C>T p.F362= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99464506; called by muse, mutect2, varscan2
- ANKS1A | c.2157G>C p.L719= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100832935; called by muse, mutect2, varscan2
- C1orf94 | c.1585C>T p.L529= (on ENST00000488417 / NM_001134734.2; = p.L339= on NM_032884.5) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100975277; called by muse, mutect2, varscan2
- CA11 | c.564C>G p.V188= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99320907; called by mutect2, varscan2
- CMTM7 | c.527G>A p.*176= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100570023; called by muse, mutect2, varscan2
- EEF2 | c.1683G>A p.L561= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100501030; called by muse, mutect2, varscan2
- FIBIN | c.501C>G p.V167= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100590549; called by muse, mutect2, varscan2
- FRMD8 | c.429G>A p.E143= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100454918; called by muse, mutect2, varscan2
- GAS2L3 | c.1090C>T p.L364= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV99903223; called by muse, mutect2
- GOLGA5 | c.918G>C p.V306= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99371342; called by muse, mutect2, varscan2
- GPR158 | c.2442C>T p.L814= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100894403; called by muse, mutect2
- GRM1 | c.606G>A p.L202= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV51226965; called by muse, mutect2, varscan2
- H4C7 | c.207C>T p.Y69= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV55099799; called by muse, mutect2, varscan2
- HHLA2 | c.171C>T p.S57= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs370821029; called by muse, mutect2, varscan2
- ITIH2 | c.1849C>T p.L617= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs185876928; called by muse, mutect2, varscan2
- JAKMIP1 | c.1191C>T p.F397= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV51529958; called by muse, mutect2
- LIME1 | c.720C>T p.L240= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as COSV55508658, COSV99829750; called by muse, mutect2, varscan2
- LTBP2 | c.588G>A p.Q196= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100001084; called by muse, mutect2
- MYO18B | c.6750C>G p.L2250= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100125446; called by muse, mutect2, varscan2
- MYO9B | c.498C>G p.L166= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV101262007, COSV101262036; called by muse, mutect2
- MYT1 | c.2208G>A p.K736= | Silent (SNP) | VAF 61/113 reads (54%) | catalogued as COSV100115626; called by muse, mutect2, varscan2
- NETO1 | c.1068C>A p.L356= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as COSV100199879, COSV55010777; called by muse, mutect2, varscan2
- NR2F6 | c.300C>A p.I100= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV52243815, COSV99360319; called by muse, mutect2, varscan2
- NUP98 | c.441C>G p.L147= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100263632, COSV61435940; called by muse, mutect2, varscan2
- PCDH7 | c.393C>T p.V131= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100688733, COSV62344379; called by muse, mutect2, varscan2
- PDZRN3 | c.1860C>T p.F620= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99732551; called by muse, mutect2, varscan2
- PPP3CC | c.576C>G p.L192= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99252519; called by muse, mutect2, varscan2
- PRKG2 | c.63C>T p.L21= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs762185624, COSV100020674; called by muse, mutect2, varscan2
- PRL | c.333G>A p.L111= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100123262, COSV60592996; called by muse, mutect2
- SLC49A4 | c.1098G>C p.L366= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV53746226; called by muse, mutect2
- SV2C | c.1521C>T p.F507= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100456907, COSV59226398; called by muse, mutect2, varscan2
- TBX18 | c.1113C>G p.S371= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV100858605; called by muse, mutect2, varscan2
- THSD7A | c.2349C>T p.C783= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs754296758, COSV101448940; called by muse, mutect2, varscan2
- TLN1 | c.1548T>C p.F516= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100148329; called by muse, mutect2, varscan2
- TPO | c.2586C>T p.F862= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs751524312, COSV100222365; called by muse, mutect2, varscan2
- WDR7 | c.3025C>T p.L1009= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99590608; called by muse, mutect2, varscan2
- XIRP1 | c.2370C>T p.I790= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1188433863, COSV100454052; called by muse, mutect2, varscan2
- ZNF418 | c.108G>A p.E36= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as rs186200644; called by muse, mutect2, varscan2
- ZNF598 | c.2670C>T p.D890= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as rs201746693; called by muse, mutect2, varscan2
- ZNF776 | c.1509C>T p.L503= | Silent (SNP) | VAF 6/137 reads (4%) | catalogued as COSV100414356; called by muse, mutect2
- POLA1 | c.2947-21199G>A | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
